Somatic mutation profile of tumor specimen MMRF_1167_1_BM_CD138pos (aliquot MMRF_1167_1_BM_CD138pos_T1_KBS5U_L02854) from MMRF case MMRF_1167, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.3 years (27,123 days).
Specimen MMRF_1167_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1bdf3f6-47c8-47a8-a204-69eaee50eaa5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1167_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1167_1_PB_WBC_C3_KBS5U_L02866; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d23ed3d-f269-48a1-bff3-a972d7ffa31c

The open-access MAF lists 186 somatic variants for this specimen: 76 protein-altering or splice-affecting, 19 silent, 91 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, 3'UTR 58, Silent 19, Intron 18, RNA 6, Nonsense Mutation 4, Splice Region 4, 5'Flank 4, 5'UTR 3, 3'Flank 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.414); catalogued as rs782504245; called by muse, mutect2, varscan2
- ANO10 | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs77313263; called by muse, mutect2, varscan2
- ATP7B | c.2136G>C p.W712C | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as CM139958, COSV54445184; called by muse, mutect2, varscan2
- CAMK2B | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs201975711, COSV51661444; called by muse, mutect2, varscan2
- CAT | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99573476; called by muse, mutect2, varscan2
- CHRD | c.2586C>A p.D862E | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.571); catalogued as rs753981487; called by muse, mutect2, varscan2
- ETV5 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.469); catalogued as rs377733507; called by muse, mutect2, varscan2
- FRAS1 | c.7632C>A p.S2544R | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV99351580; called by muse, mutect2, varscan2
- GABRR1 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 55/76 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101034021; called by muse, mutect2
- H1-7 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as rs1238152408; called by muse, mutect2, varscan2
- HSPA4L | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99613475; called by muse, mutect2, varscan2
- IGHV2-70 | c.313A>G p.N105D | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs377238058; called by muse, varscan2
- IGLV9-49 | c.162G>C p.W54C | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs774696685; called by muse, mutect2, varscan2
- LRRIQ3 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV63045962; called by muse, mutect2, varscan2
- MYO1G | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as rs141469545; called by muse, mutect2, varscan2
- OR8B8 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 83/265 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs267602760, COSV60145155, COSV60145465; called by muse, mutect2, varscan2
- PHF21B | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs762636382, COSV57559570; called by muse, mutect2, varscan2
- PKN1 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 7/147 reads (5%) | catalogued as COSV99661599; called by muse, mutect2
- POT1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 128/379 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV62930125; called by muse, mutect2, varscan2
- PWWP3A | c.1687G>A p.D563N (on ENST00000627377; = p.D562N on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773933247; called by muse, mutect2, varscan2
- SART3 | c.1744A>G p.I582V (on ENST00000228284; = p.I564V on NM_014706.4) | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755082369; called by muse, mutect2, varscan2
- SPRED1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs750832911, COSV100136071; called by muse, mutect2, varscan2
- TGDS | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54300527, COSV99725238; called by muse, mutect2, varscan2
- WDR87 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs1019116355, COSV58202577; called by muse, mutect2, varscan2
- ZC3H3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765443312, COSV52791120; called by muse, mutect2, varscan2
- ZNF835 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as rs755139450, COSV73379292; called by muse, mutect2, varscan2
- AASS | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ADAM18 | c.2177+7_2177+22del | Splice Region (DEL) | VAF 10/11 reads (91%) | called by mutect2, varscan2
- ADCY8 | c.910G>T p.V304F | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANPEP | c.2160C>T p.N720= | Splice Region (SNP) | VAF 73/119 reads (61%) | called by muse, mutect2, varscan2
- ASPM | c.4469G>T p.C1490F | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATP8B4 | c.1946A>G p.E649G | Missense Mutation (SNP) | VAF 128/200 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, varscan2
- BEGAIN | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C15orf39 | c.687G>T p.R229S | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- CALHM3 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC85A | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC6 | c.626C>G p.T209S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); called by muse, mutect2
- CLK1 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLTCL1 | c.1419G>C p.M473I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL6A6 | c.6250G>T p.V2084F | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CTAG2 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 126/129 reads (98%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DENND4A | c.3139A>G p.I1047V | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- F8 | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 119/120 reads (99%) | called by muse, mutect2, varscan2
- GLTPD2 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GNA15 | c.330+1G>A p.X110_splice | Splice Site (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- H4-16 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- IGHV1-69D | c.283A>T p.T95S | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- IGLV4-60 | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- IQCG | c.1200C>G p.L400= | Splice Region (SNP) | VAF 105/377 reads (28%) | called by muse, mutect2, varscan2
- KLF15 | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- LY86 | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIA2 | c.2179A>C p.M727L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MOV10L1 | c.3164C>A p.S1055Y | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MUC16 | c.10558T>C p.S3520P | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- MYBL1 | c.1481C>A p.T494K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NAP1L1 | c.1141-1G>A p.X381_splice | Splice Site (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- ORC4 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- PASD1 | c.1474C>A p.Q492K | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0.387); called by muse, varscan2
- PTPRG | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- PVRIG | c.74C>A p.T25N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- RAB6D | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RABGAP1 | c.1219A>G p.M407V | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RB1 | c.2031_2038del p.E677Dfs*12 | Frame Shift Del (DEL) | VAF 68/78 reads (87%) | called by mutect2, pindel, varscan2
- REV3L | c.6764C>T p.A2255V | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SCN11A | c.4297G>A p.D1433N | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SSR3 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SYT17 | c.1352T>C p.V451A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TAAR8 | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TDRD12 | c.2107T>A p.L703M | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- TMEM211 | c.223G>T p.G75* (on ENST00000423535; = p.G4* on NM_001001663.3) | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | called by muse, varscan2
- TMSB4X | c.-19C>T | Splice Region (SNP) | VAF 60/63 reads (95%) | called by muse, mutect2, varscan2
- VCP | c.1633C>G p.P545A | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WRN | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 63/64 reads (98%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF354C | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ZNF541 | c.2828G>T p.S943I | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ZNF862 | c.2283C>A p.N761K | Missense Mutation (SNP) | VAF 55/76 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ACTG1 | c.57T>A p.A19= | Silent (SNP) | VAF 116/308 reads (38%) | called by muse, mutect2, varscan2
- ANKRD17 | c.5067T>C p.T1689= | Silent (SNP) | VAF 57/113 reads (50%) | called by muse, mutect2, varscan2
- ATF7IP | c.378T>G p.P126= | Silent (SNP) | VAF 77/154 reads (50%) | called by muse, mutect2, varscan2
- CPVL | c.888C>T p.G296= | Silent (SNP) | VAF 59/178 reads (33%) | catalogued as rs370525550, COSV55298929, COSV55301485; called by muse, varscan2
- ELF5 | c.744G>A p.R248= (on ENST00000312319 / NM_198381.2; = p.R238= on NM_001422.4) | Silent (SNP) | VAF 347/512 reads (68%) | called by muse, mutect2, varscan2
- FMN1 | c.4017A>G p.P1339= (on ENST00000616417 / NM_001277313.2; = p.P1116= on NM_001103184.4) | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as rs1226921455; called by muse, mutect2
- GABRD | c.93C>T p.Y31= | Silent (SNP) | VAF 117/228 reads (51%) | catalogued as rs768454474, COSV101059549; called by muse, mutect2, varscan2
- KIF26A | c.2808G>A p.P936= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs200138034; called by muse, mutect2, varscan2
- PCDHA6 | c.1281G>A p.A427= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV67026394; called by muse, mutect2, varscan2
- PCDHAC2 | c.426C>T p.N142= | Silent (SNP) | VAF 52/148 reads (35%) | catalogued as COSV53838352; called by muse, mutect2, varscan2
- PLEKHG3 | c.1341C>T p.S447= (on ENST00000394691; = p.S503= on NM_001308147.2) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs1474210807; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1038C>T p.F346= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs775438464, COSV57926598; called by muse, mutect2, varscan2
- RNASE7 | c.210C>A p.T70= | Silent (SNP) | VAF 44/246 reads (18%) | called by muse, mutect2, varscan2
- RSPH6A | c.264A>T p.P88= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- TNRC18 | c.2430C>T p.N810= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs372198870; called by muse, mutect2
- TST | c.816C>T p.Y272= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs375756604; called by muse, mutect2, varscan2
- WNK4 | c.1422C>T p.I474= | Silent (SNP) | VAF 40/158 reads (25%) | called by muse, mutect2, varscan2
- XRN1 | c.2853A>C p.A951= | Silent (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- ZNF831 | c.1155C>G p.V385= | Silent (SNP) | VAF 45/68 reads (66%) | catalogued as rs765050349, COSV64044959; called by muse, mutect2, varscan2
- AC093155.3 | c.*50C>T | 3'UTR (SNP) | VAF 99/236 reads (42%) | catalogued as rs758354698; called by muse, mutect2, varscan2
- AC114741.1 | n.446G>T | RNA (SNP) | VAF 31/47 reads (66%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1847A>G | RNA (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- ANHX | c.*262A>G | 3'UTR (SNP) | VAF 71/144 reads (49%) | called by muse, mutect2, varscan2
- ANK2 | c.85-57229C>T | Intron (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- ANKAR | c.1203+47del | Intron (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- ANO3 | c.591+254G>A | Intron (SNP) | VAF 76/107 reads (71%) | called by muse, mutect2, varscan2
- ARID5B | c.*3265C>T | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- ARRDC4 | c.*2242A>G | 3'UTR (SNP) | VAF 46/140 reads (33%) | called by muse, mutect2, varscan2
- ARSD | c.*569_*581del | 3'UTR (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- ASIC2 | c.556-180423G>A | Intron (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021570 C>G | 5'Flank (SNP) | VAF 21/47 reads (45%) | catalogued as COSV55848051; called by muse, mutect2, varscan2
- C9orf116 | chr9:135500386 G>T | 5'Flank (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- CACNA1A | c.4401-79C>G | Intron (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2
- CACYBP | c.530+121G>A | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- CFAP20DC | c.*145A>T | 3'UTR (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- COX5B | c.*12A>G | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.1006+12A>G | Intron (SNP) | VAF 77/223 reads (35%) | called by muse, mutect2, varscan2
- DKK3 | c.*905C>T | 3'UTR (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*2899C>A | 3'UTR (SNP) | VAF 23/25 reads (92%) | called by muse, mutect2, varscan2
- EIF4E | c.*4750A>G | 3'UTR (SNP) | VAF 18/23 reads (78%) | called by muse, mutect2, varscan2
- ENTPD3 | c.*806T>C | 3'UTR (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- EPHA3 | c.1594+246del | Intron (DEL) | VAF 14/44 reads (32%) | called by pindel, varscan2
- EPHA5 | c.*2784T>C | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- FBXL7 | c.*626G>A | 3'UTR (SNP) | VAF 29/107 reads (27%) | catalogued as rs1325598889; called by muse, mutect2, varscan2
- FREM3 | c.*16A>G | 3'UTR (SNP) | VAF 41/82 reads (50%) | catalogued as COSV100318273; called by muse, mutect2, varscan2
- GLI3 | c.*3118dup | 3'UTR (INS) | VAF 14/135 reads (10%) | catalogued as rs1022327737; called by mutect2, varscan2
- GPR32P1 | n.265C>T | RNA (SNP) | VAF 17/166 reads (10%) | catalogued as rs545719809; called by muse, mutect2, varscan2
- GTPBP10 | c.*4839G>T | 3'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- GUCY2EP | n.1077C>T | RNA (SNP) | VAF 213/321 reads (66%) | catalogued as rs1018258482; called by muse, mutect2, varscan2
- H2BC7 | c.*127G>C | 3'UTR (SNP) | VAF 51/158 reads (32%) | called by muse, mutect2, varscan2
- H2BP2 | n.528dup | RNA (INS) | VAF 59/164 reads (36%) | catalogued as rs1158919178; called by mutect2, varscan2
- HRNR | c.*426A>G | 3'UTR (SNP) | VAF 37/111 reads (33%) | catalogued as rs1024270324; called by muse, mutect2, varscan2
- ID4 | c.-307C>T | 5'UTR (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- IGLV1-47 | c.-38C>G | 5'UTR (SNP) | VAF 28/50 reads (56%) | called by muse, varscan2
- KCNB1 | c.*2533G>A | 3'UTR (SNP) | VAF 27/75 reads (36%) | called by muse, varscan2
- KCND3 | chr1:111773075 G>A | 3'Flank (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- KCTD20 | c.*543G>A | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- KIAA0319L | c.*927G>A | 3'UTR (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- KRBOX1 | c.-47+429G>T | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- LINC02228 | n.415G>T | RNA (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- LMOD1 | c.*1012G>A | 3'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- LPIN1 | c.722+2413C>T | Intron (SNP) | VAF 22/50 reads (44%) | catalogued as rs1209206191; called by muse, mutect2, varscan2
- LRRC27 | chr10:132378683 del G | 3'Flank (DEL) | VAF 41/105 reads (39%) | called by mutect2, pindel, varscan2
- MARCHF8 | c.*1173C>T | 3'UTR (SNP) | VAF 51/114 reads (45%) | called by muse, mutect2, varscan2
- MINAR1 | c.*148G>A | 3'UTR (SNP) | VAF 56/130 reads (43%) | called by muse, mutect2, varscan2
- MORC3 | c.*1088T>G | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- MYO10 | c.*212T>C | 3'UTR (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- NEK10 | c.569-28C>T | Intron (SNP) | VAF 56/156 reads (36%) | catalogued as rs1406068664; called by muse, mutect2, varscan2
- NKD2 | c.*94G>C | 3'UTR (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- NPTX2 | c.*356C>T | 3'UTR (SNP) | VAF 41/134 reads (31%) | called by muse, mutect2, varscan2
- OLFM3 | c.*643A>T | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- PAX6 | c.10+928C>T | Intron (SNP) | VAF 84/123 reads (68%) | called by muse, mutect2, varscan2
- PBX1 | c.*783G>A | 3'UTR (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- PCDH15 | c.*407C>A | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- PDE4D | c.456-59657_456-59656insCC | Intron (INS) | VAF 16/56 reads (29%) | called by mutect2, pindel*, varscan2
- PDHX | chr11:34916394 G>A | 5'Flank (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2
- PFKM | c.*21A>C | 3'UTR (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2
- PI15 | c.*1G>A | 3'UTR (SNP) | VAF 26/141 reads (18%) | called by muse, mutect2, varscan2
- PITPNB | c.*1560G>T | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- POMT2 | c.*478T>C | 3'UTR (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- PPP1R1A | c.*336_*338del | 3'UTR (DEL) | VAF 41/102 reads (40%) | called by pindel, varscan2
- PTPRT | c.*3547G>A | 3'UTR (SNP) | VAF 54/166 reads (33%) | called by muse, mutect2, varscan2
- PUM2 | c.*814G>C | 3'UTR (SNP) | VAF 110/150 reads (73%) | called by muse, mutect2, varscan2
- RABEP1 | c.528+1269G>A | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as rs1337900518; called by muse, mutect2, varscan2
- RAPGEFL1 | c.*509T>C | 3'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- RBM18 | c.*1117G>A | 3'UTR (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- RHOQ | c.*1122T>A | 3'UTR (SNP) | VAF 80/886 reads (9%) | called by muse, mutect2
- RIMS2 | c.*29A>T | 3'UTR (SNP) | VAF 51/178 reads (29%) | called by muse, mutect2, varscan2
- RNF217 | c.*2795A>C | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- RPL37 | c.*1752G>A | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- RRBP1 | c.*285G>T | 3'UTR (SNP) | VAF 68/173 reads (39%) | called by muse, mutect2, varscan2
- RRP8 | c.918-35C>G | Intron (SNP) | VAF 122/356 reads (34%) | called by muse, mutect2, varscan2
- SCRT2 | c.*1102C>A | 3'UTR (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- SDAD1 | c.*114G>C | 3'UTR (SNP) | VAF 68/145 reads (47%) | called by muse, mutect2, varscan2
- SEMA3A | c.*2357T>A | 3'UTR (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- SHISA9 | c.564-5605G>C | Intron (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- SPG11 | c.*155T>G | 3'UTR (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- ST13 | c.*478T>A | 3'UTR (SNP) | VAF 57/119 reads (48%) | called by muse, mutect2, varscan2
- SUCLG1 | c.*18T>G | 3'UTR (SNP) | VAF 81/374 reads (22%) | called by mutect2, varscan2
- SUN1 | c.*658G>T | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- TCTN3 | c.*25_*41del | 3'UTR (DEL) | VAF 57/157 reads (36%) | called by mutect2, pindel, varscan2
- TMEM167B | c.*1133C>G | 3'UTR (SNP) | VAF 5/66 reads (8%) | catalogued as rs1002705432; called by muse, mutect2
- TMPO | c.*421A>G | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- TPP1 | chr11:6619492 T>C | 5'Flank (SNP) | VAF 74/480 reads (15%) | catalogued as rs996414084; called by muse, mutect2, varscan2
- TRDN | c.794-1288A>G | Intron (SNP) | VAF 173/292 reads (59%) | catalogued as rs1318866747; called by muse, mutect2, varscan2
- TSC2 | c.3883+19A>G | Intron (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- XPR1 | c.*709G>A | 3'UTR (SNP) | VAF 33/104 reads (32%) | catalogued as rs902679308; called by muse, mutect2, varscan2
- ZNF747 | c.-352C>T | 5'UTR (SNP) | VAF 34/60 reads (57%) | catalogued as rs1224616431; called by muse, varscan2
- ZNF766 | c.*15A>C | 3'UTR (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.*693_*696del | 3'UTR (DEL) | VAF 6/28 reads (21%) | catalogued as rs1347319274; called by mutect2, pindel, varscan2
